Gene-level copy-number profile of tumor specimen TCGA-ZP-A9D4-01A from TCGA case TCGA-ZP-A9D4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 64.8 years (23,656 days).
Specimen TCGA-ZP-A9D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.71a3fcbb-d396-4dd2-ade8-c6094607ceaf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZP-A9D4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f60d118-dae4-4397-a211-1d8d79f81c53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,777; copy number 2: 49,958; copy number 3: 340; copy number 4: 6,493; copy number 5: 162; copy number 6: 49; copy number 8: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZP-A9D4-01A-11D-A36W-01): tumor purity 0.87, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 246 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:892,884–1,295,068, 14 genes, copy number 6: TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:25,404,733–28,809,291, 24 genes, copy number 5–8: AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2.
- chr5:31,053,565–31,267,610, 3 genes, copy number 5 (within-gene range 2–5): RPL19P11, AC026421.1, AC113386.1.
- chr5:31,400,497–32,312,987, 29 genes, copy number 5 (within-gene range 2–5): DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P.
- chr5:32,394,378–32,394,475, 1 gene, copy number 5: MIR579.
- chr5:32,531,633–37,753,435, 88 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr5:45,890,216–45,895,970, 1 gene, copy number 5: AC122694.1.
- chr5:53,560,633–53,819,722, 2 genes, copy number 5: NDUFS4, LINC02105.
- chr5:145,337,932–145,451,108, 2 genes, copy number 6 (within-gene range 3–6): AC137770.1, AC008700.1.
- chr5:149,492,982–149,944,793, 11 genes, copy number 5 (within-gene range 3–5): CSNK1A1, AC021078.1, RPL29P14, ARHGEF37, RNU6-588P, AC022100.1, U3, RN7SL868P, PPARGC1B, MIR378A, PDE6A.
- chr5:151,276,358–151,924,851, 25 genes, copy number 5 (within-gene range 3–5): SLC36A3, SLC36A2, ATP6V1G1P5, AC034205.2, AC034205.1, AC034205.3, SLC36A1, RNA5SP197, FAT2, AC011337.1, MIR6499, AC011374.3, AC011374.1, SPARC, CLMAT3, RN7SKP232, AC011374.2, ATOX1, AC091982.1, RPLP1P6, AC091982.3, G3BP1, GLRA1, AC091982.2, RNA5SP198.
- chr5:155,397,291–156,852,528, 9 genes, copy number 5: AC010591.1, AC008725.1, RNA5SP199, SGCD, AC011351.1, AC027308.1, AC025434.1, RNU6-556P, PPP1R2B.
- chr5:156,924,119–156,924,710, 1 gene, copy number 5: APOOP1.
- chr5:160,187,367–162,162,977, 24 genes, copy number 6: FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2, ZBED8, SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A, ATP10B, AC008456.1, AC011363.1, LINC02159, GABRB2, GABRA6, AC091944.1, GLRXP3, GABRA1, LINC01202, GABRG2.
- chr5:162,477,891–162,762,313, 2 genes, copy number 6: RNU6-164P, ARL2BPP5.
- chr5:163,796,065–163,887,827, 3 genes, copy number 5: RNU6-168P, AC008432.1, LSM1P2.
- chr5:165,349,030–166,382,599, 7 genes, copy number 6 (within-gene range 2–6): AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.

Autosomal genes at a single copy (total copy number 1): 2,777. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
